Somatic mutation profile of tumor specimen TCGA-DK-A3WW-01A (aliquot TCGA-DK-A3WW-01A-22D-A23M-08) from TCGA case TCGA-DK-A3WW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 57.2 years (20,909 days).
Specimen TCGA-DK-A3WW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85445f37-d03f-4daf-b176-f3bce72bbac9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3WW-10A (Blood Derived Normal), aliquot TCGA-DK-A3WW-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c603acbd-10a9-4020-9c01-d447f1de4182

The open-access MAF lists 1,370 somatic variants for this specimen: 994 protein-altering or splice-affecting, 340 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 862, Silent 340, Nonsense Mutation 99, RNA 15, Intron 14, Splice Site 14, Splice Region 9, Frame Shift Del 7, 3'UTR 3, 5'UTR 3, Nonstop Mutation 2, 3'Flank 1.

Variants (750 of 1,370; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MITF | c.937G>C p.E313Q (on ENST00000448226 / NM_006722.3; = p.E213Q on NM_000248.4) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057522775, COSV58830849; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RP1 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs104894082, CD992276, CM991103, COSV55128917; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2
- AASS | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV62789651; called by muse, mutect2, varscan2
- ABCA1 | c.4202C>T p.T1401I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs372821558; called by muse, mutect2, varscan2
- ABCA10 | c.3511G>C p.D1171H | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs140554607; called by muse, mutect2, varscan2
- ABCC3 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV53320023; called by muse, mutect2, varscan2
- ABCG5 | c.1377G>C p.Q459H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV53210367; called by muse, mutect2, varscan2
- AC004593.2 | c.579G>C p.K193N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV56090718, COSV56101711; called by muse, mutect2, varscan2
- AC004832.3 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV56741444, COSV56741663; called by muse, mutect2, varscan2
- AC109583.1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as rs770494012, COSV58405536; called by muse, mutect2, varscan2
- ACAA1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV57173071; called by muse, mutect2, varscan2
- ACAN | c.4274G>C p.G1425A | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV61359013; called by muse, varscan2
- ACAN | c.7546G>C p.E2516Q (on ENST00000560601 / NM_001369268.1; = p.E2478Q on NM_013227.3) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.925); catalogued as COSV61359021; called by muse, varscan2
- ACIN1 | c.1733C>G p.S578C | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV52975277; called by muse, mutect2, varscan2
- ACP3 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60485486; called by muse, mutect2, varscan2
- ACP5 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54535982; called by muse, mutect2, varscan2
- ACTA1 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV64203184; called by muse, mutect2, varscan2
- ACTB | c.1043C>G p.S348W | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV59317066, COSV59317805; called by muse, mutect2, varscan2
- ACTL6A | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66998861; called by muse, mutect2, varscan2
- ACTR6 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.146); catalogued as COSV51841589, COSV99498833; called by muse, mutect2, varscan2
- ACTR8 | c.1054C>G p.H352D | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV51636011, COSV51636844; called by muse, mutect2, varscan2
- ADAM18 | c.826G>C p.V276L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs747432229, COSV55846123; called by muse, mutect2, varscan2
- ADAM29 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); catalogued as rs1301611574, COSV100822198, COSV63662573; called by muse, mutect2, varscan2
- ADAM30 | c.2300G>A p.G767E | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV65560851; called by muse, mutect2, varscan2
- ADAMTS20 | c.2998C>T p.R1000C | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as rs369101503; called by muse, mutect2, varscan2
- ADAMTS6 | c.2110G>C p.D704H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66858805; called by muse, mutect2, varscan2
- ADCY4 | c.726G>C p.E242D | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); catalogued as COSV53474974; called by muse, mutect2, varscan2
- ADCY6 | c.3107C>T p.T1036I | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1425378025, COSV57167178; called by muse, mutect2, varscan2
- ADCY8 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV53894881, COSV53907491, COSV53918807; called by muse, mutect2, varscan2
- ADGRB3 | c.1088G>C p.R363P | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65391221; called by muse, mutect2, varscan2
- ADGRV1 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.854); catalogued as rs1225831618, COSV67986231; called by muse, mutect2, varscan2
- AGAP3 | c.1415C>T p.S472F (on ENST00000622464; = p.S508F on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); catalogued as rs867657542, COSV68244113; called by mutect2, varscan2
- AGAP6 | c.1543G>A p.D515N (on ENST00000374056 / NM_001365867.1; = p.D538N on NM_001077665.2) | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); catalogued as COSV65017562; called by muse, mutect2, varscan2
- AGO2 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55046602; called by muse, mutect2, varscan2
- AGO3 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV55792802; called by muse, mutect2, varscan2
- AGTPBP1 | c.1633C>T p.Q545* (on ENST00000357081 / NM_001330701.2; = p.Q505* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100429944; called by muse, mutect2, varscan2
- AHNAK | c.8665G>C p.D2889H | Missense Mutation (SNP) | VAF 82/357 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV57210571; called by muse, varscan2
- AHNAK | c.8472G>C p.K2824N | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57210584; called by muse, varscan2
- AHNAK | c.7461G>A p.M2487I | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57210600, COSV99947783; called by muse, mutect2, varscan2
- AHNAK2 | c.6610C>T p.Q2204* | Nonsense Mutation (SNP) | VAF 83/240 reads (35%) | catalogued as rs1042260739, COSV100316462; called by muse, varscan2
- AKAP17A | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.44); catalogued as rs746576789, COSV100002096; called by muse, mutect2
- AKT3 | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55613732; called by muse, mutect2, varscan2
- ALPK2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV64492119; called by muse, mutect2, varscan2
- AMOTL2 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs554840600, COSV51437856; called by muse, mutect2, varscan2
- ANAPC4 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 33/123 reads (27%) | catalogued as rs1170556411; called by muse, mutect2, varscan2
- ANAPC5 | c.1576C>T p.H526Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV55842355; called by muse, mutect2, varscan2
- ANK3 | c.12987G>A p.M4329I (on ENST00000280772 / NM_001320874.2; = p.M953I on NM_001149.3) | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as rs763252744, COSV55053244; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV51844936; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7784C>G p.S2595C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV51844994; called by muse, mutect2, varscan2
- ANO5 | c.2420G>C p.R807T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV61084006; called by muse, mutect2, varscan2
- ANXA6 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV62906321; called by muse, mutect2, varscan2
- AP2A2 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV59959703; called by muse, mutect2, varscan2
- AP2B1 | c.1723C>T p.H575Y | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV51998626; called by muse, mutect2, varscan2
- APLNR | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57241937; called by muse, mutect2, varscan2
- ARAP1 | c.1689C>G p.I563M (on ENST00000393609 / NM_001040118.2; = p.I318M on NM_015242.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61990698; called by muse, mutect2, varscan2
- ARFGAP3 | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54311460; called by muse, mutect2, varscan2
- ARFGEF1 | c.3209del p.S1070Lfs*25 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | catalogued as COSV51603782, COSV51606497; called by mutect2, pindel, varscan2
- ARHGAP29 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53110593; called by muse, mutect2, varscan2
- ARHGAP6 | c.2732G>C p.G911A (on ENST00000337414 / NM_013427.3; = p.G708A on NM_013423.3) | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV57294525; called by muse, mutect2, varscan2
- ARHGEF15 | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.859); catalogued as COSV62724887; called by muse, mutect2, varscan2
- ARHGEF19 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs947080338, COSV54616175; called by muse, mutect2
- ARMC9 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs779229688, COSV63020356; called by muse, mutect2, varscan2
- ARMC9 | c.1523C>A p.S508* | Nonsense Mutation (SNP) | VAF 42/156 reads (27%) | catalogued as COSV100589641, COSV63022614; called by muse, varscan2
- ARNTL2 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV53825021; called by muse, mutect2, varscan2
- ARPC2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs1362317685, COSV55284320; called by muse, mutect2, varscan2
- ARSA | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 91/166 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.141); catalogued as COSV53350281; called by muse, mutect2, varscan2
- ARSK | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV66169508; called by muse, mutect2, varscan2
- ASB11 | c.474G>C p.Q158H | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.694); catalogued as COSV60354877; called by muse, mutect2, varscan2
- ASCL3 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV57941086, COSV57941148; called by muse, mutect2, varscan2
- ASH1L | c.7567G>A p.E2523K (on ENST00000368346 / NM_001366177.2; = p.E2518K on NM_018489.3) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV64207092; called by muse, mutect2, varscan2
- ASIC1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs768474356, COSV57317532; called by muse, mutect2, varscan2
- ASTN1 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99920711; called by muse, mutect2, varscan2
- ASXL1 | c.1730C>G p.S577* | Nonsense Mutation (SNP) | VAF 19/127 reads (15%) | catalogued as COSV60104299, COSV60105748; called by muse, mutect2, varscan2
- ASXL3 | c.2189C>T p.S730L | Missense Mutation (SNP) | VAF 57/279 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1207965286, COSV52463263; called by muse, mutect2, varscan2
- ATF6 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 25/134 reads (19%) | catalogued as COSV63407583; called by muse, mutect2, varscan2
- ATG9A | c.2396C>G p.S799C | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); catalogued as COSV54694936; called by muse, mutect2, varscan2
- ATM | c.6490G>C p.E2164Q | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1317619286, COSV53730905, COSV53774759; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.6814G>T p.E2272* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as CM030779, COSV53744239, COSV99588352; called by muse, varscan2
- ATOH7 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV65447660, COSV65447758; called by muse, mutect2, varscan2
- ATP10B | c.4313G>C p.R1438T | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV59148751; called by muse, mutect2, varscan2
- ATP10D | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56706503; called by muse, mutect2, varscan2
- ATP13A2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs540184864, COSV58699729, COSV58704089; called by muse, mutect2, varscan2
- ATP2B4 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV58176602; called by muse, mutect2, varscan2
- ATXN3 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as COSV61494718; called by muse, mutect2, varscan2
- B3GNT5 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.621); catalogued as rs752364337, COSV58475791, COSV58476555; called by muse, mutect2
- B3GNT5 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.168); catalogued as COSV58475229, COSV58475801; called by muse, mutect2
- BABAM2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs376668252, COSV59616856; called by muse, mutect2
- BCL9 | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs782111632, COSV52341646; called by muse, varscan2
- BEND7 | c.962G>C p.R321T | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV61988322; called by muse, mutect2, varscan2
- BIRC6 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV70198015; called by muse, mutect2, varscan2
- BIRC6 | c.4696C>G p.L1566V | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70198022; called by muse, mutect2, varscan2
- BLOC1S5 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV55241167; called by muse, mutect2, varscan2
- BORA | c.1552G>C p.D518H (on ENST00000613797; = p.D443H on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64695130; called by muse, mutect2, varscan2
- BRIP1 | c.2524C>G p.L842V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs786201802, COSV51997773; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTBD10 | c.906G>C p.Q302H | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV53398687; called by muse, mutect2, varscan2
- BTN2A1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57002947; called by muse, varscan2
- BUB1 | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57062786; called by muse, mutect2, varscan2
- BUD31 | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.344); catalogued as COSV52862667; called by muse, mutect2, varscan2
- C10orf88 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV64403870; called by muse, mutect2, varscan2
- C11orf1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV52788012; called by muse, mutect2, varscan2
- C11orf49 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 50/191 reads (26%) | catalogued as rs14051, COSV53568768, COSV53569395; called by muse, mutect2, varscan2
- C12orf40 | c.185G>C p.C62S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.303); catalogued as COSV100210158, COSV61131252; called by muse, mutect2, varscan2
- C16orf46 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); catalogued as COSV55150792; called by muse, mutect2, varscan2
- C2orf49 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.881); catalogued as COSV51527458; called by muse, mutect2, varscan2
- C2orf68 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV60472712; called by muse, mutect2, varscan2
- C4orf17 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV58511837; called by muse, mutect2, varscan2
- C9orf50 | c.966G>C p.E322D | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as rs751951762, COSV65252329; called by muse, mutect2, varscan2
- CA4 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs1222368586, COSV56281330; called by muse, mutect2, varscan2
- CABP1 | c.712G>C p.D238H (on ENST00000316803 / NM_001033677.1; = p.D35H on NM_004276.5) | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56457967, COSV56458311; called by muse, mutect2, varscan2
- CACNA1A | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV64195470; called by muse, mutect2, varscan2
- CACNA1S | c.4353G>A p.M1451I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs773780364, COSV62938663; called by muse, mutect2, varscan2
- CACNA1S | c.4206C>G p.F1402L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62938667; called by muse, mutect2, varscan2
- CACNA1S | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62938672, COSV62939252; called by muse, mutect2, varscan2
- CACNA2D1 | c.2209G>C p.D737H (on ENST00000356253 / NM_001366867.1; = p.D725H on NM_000722.4) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV62377295; called by muse, mutect2, varscan2
- CADPS | c.2554C>T p.R852W | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs779578391, COSV104368322, COSV51875283; called by muse, mutect2, varscan2
- CAPNS2 | c.669C>G p.F223L | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs1449167224, COSV50894937; called by muse, mutect2, varscan2
- CARF | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.084); catalogued as COSV57547266; called by muse, mutect2, varscan2
- CARMIL2 | c.939G>C p.Q313H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV58031253; called by muse, mutect2
- CARMIL2 | c.1615C>G p.L539V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58025121; called by muse, varscan2
- CASP8 | c.632C>G p.S211C (on ENST00000432109 / NM_033355.3; = p.S228C on NM_001228.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV51847239; called by muse, mutect2, varscan2
- CASP9 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747615996, COSV61601303, COSV61601336, COSV61601421; called by muse, mutect2, varscan2
- CATSPER1 | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV56410049; called by muse, mutect2, varscan2
- CATSPER3 | c.993G>C p.L331F | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV50945885; called by muse, mutect2, varscan2
- CC2D2B | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100729377, COSV60357684; called by muse, mutect2, varscan2
- CCDC130 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55583068, COSV99681186; called by muse, varscan2
- CCDC138 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV54566201; called by muse, mutect2, varscan2
- CCDC144A | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV60697763; called by muse, varscan2
- CCDC178 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV55769162, COSV55793829; called by muse, mutect2, varscan2
- CCDC27 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV53899604; called by muse, mutect2, varscan2
- CCDC77 | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53472577; called by muse, mutect2, varscan2
- CCDC88A | c.5030G>A p.G1677E (on ENST00000436346 / NM_001365480.1; = p.G1649E on NM_018084.5) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV55060070; called by muse, mutect2, varscan2
- CCDC89 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57033876; called by muse, mutect2, varscan2
- CCKAR | c.755-1G>A p.X252_splice | Splice Site (SNP) | VAF 23/109 reads (21%) | catalogued as COSV55161003; called by muse, mutect2, varscan2
- CCNT1 | c.1756G>C p.D586H | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV56063958; called by muse, mutect2, varscan2
- CCR10 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV52849340; called by muse, mutect2
- CCR4 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV58382004; called by muse, mutect2, varscan2
- CD300LD | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs750999572, COSV60083606; called by muse, mutect2
- CDC40 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as COSV57008996; called by muse, mutect2, varscan2
- CDC42BPA | c.4668G>C p.Q1556H (on ENST00000334218 / NM_001366019.2; = p.Q1543H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62009021; called by muse, mutect2, varscan2
- CDC6 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV52930249; called by muse, mutect2, varscan2
- CDCP1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.744); catalogued as COSV56104795; called by muse, mutect2, varscan2
- CDH6 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54065738; called by muse, mutect2, varscan2
- CDHR5 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.229); catalogued as rs537203327, COSV51564224; called by muse, mutect2, varscan2
- CDK16 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52091780; called by muse, mutect2, varscan2
- CDK7 | c.127-1G>C p.X43_splice | Splice Site (SNP) | VAF 26/111 reads (23%) | catalogued as COSV56513011; called by muse, mutect2, varscan2
- CDKAL1 | c.1419G>C p.K473N | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV51182126; called by muse, mutect2, varscan2
- CEBPZ | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV50017275; called by muse, mutect2, varscan2
- CELSR2 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54769676; called by muse, mutect2, varscan2
- CEMP1 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.908); catalogued as COSV53550419; called by muse, mutect2, varscan2
- CENPB | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as COSV60145805; called by muse, mutect2, varscan2
- CEP164 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV54039825, COSV54040258; called by muse, mutect2, varscan2
- CEP192 | c.4268C>G p.S1423* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV58066028; called by muse, mutect2, varscan2
- CFAP251 | c.3424G>A p.E1142K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV56609630; called by muse, mutect2, varscan2
- CFAP43 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV53377432; called by muse, mutect2, varscan2
- CFAP91 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV56340367; called by muse, mutect2, varscan2
- CGN | c.881C>G p.S294* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV54968192; called by muse, mutect2, varscan2
- CHAT | c.1474C>G p.Q492E | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.316); catalogued as COSV60323347; called by muse, mutect2, varscan2
- CHD2 | c.3175G>C p.E1059Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV67708261; called by muse, mutect2, varscan2
- CHD7 | c.7723G>C p.E2575Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.684); catalogued as COSV71109188; called by muse, mutect2, varscan2
- CHRFAM7A | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.218); catalogued as rs368423557; called by muse, mutect2, varscan2
- CIDEA | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100255137, COSV57598151; called by muse, mutect2, varscan2
- CILP | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV56023356; called by muse, mutect2, varscan2
- CKAP5 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56366682; called by muse, mutect2, varscan2
- CKMT1B | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.151); catalogued as rs775737368, COSV55852222; called by muse, varscan2
- CLDN17 | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV54522681; called by muse, mutect2, varscan2
- CLN6 | c.489C>T p.I163= | Splice Region (SNP) | VAF 29/134 reads (22%) | catalogued as rs748682605, COSV51116585; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNR2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV65692708; called by muse, mutect2, varscan2
- CNTNAP4 | c.3565G>A p.D1189N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56675000; called by muse, mutect2, varscan2
- COASY | c.1108G>C p.G370R | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55898247; called by muse, mutect2, varscan2
- COL7A1 | c.8330G>C p.R2777P | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV56476367, COSV56476412; called by muse, mutect2, varscan2
- COL7A1 | c.5888G>C p.W1963S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.153); catalogued as COSV60394105; called by muse, mutect2, varscan2
- COQ6 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV53178463; called by muse, mutect2, varscan2
- COX10 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV55404332, COSV99886254; called by muse, mutect2, varscan2
- CPA1 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1554412268, COSV50568917; called by muse, mutect2, varscan2
- CPB2 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV51673517; called by muse, mutect2, varscan2
- CPNE9 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369110890, COSV56068177; called by muse, mutect2, varscan2
- CPS1 | c.2456C>G p.S819C | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51807461; called by muse, mutect2, varscan2
- CPS1 | c.3384G>C p.L1128F | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51807479; called by muse, varscan2
- CPSF4 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 83/347 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV52857188; called by muse, mutect2, varscan2
- CR2 | c.2906G>T p.R969I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100889699, COSV65507148; called by muse, varscan2
- CRABP1 | c.250-1G>A p.X84_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100211343; called by muse, mutect2
- CRTC1 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs756822056, COSV58716021; called by muse, mutect2
- CSF2RA | c.866G>C p.R289T | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs771582096, COSV62624306; called by muse, mutect2, varscan2
- CSF3R | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV58965453; called by muse, mutect2, varscan2
- CSNK1A1L | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV65789414, COSV65789570; called by muse, mutect2, varscan2
- CSTF2T | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58656249; called by muse, mutect2, varscan2
- CUL4B | c.2124C>G p.F708L | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60686568; called by muse, mutect2, varscan2
- CXXC1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1464344742, COSV53273717; called by muse, mutect2, varscan2
- CYB5D1 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.296); catalogued as COSV54680285; called by muse, mutect2, varscan2
- CYP2A13 | c.654+1G>T p.X218_splice | Splice Site (SNP) | VAF 18/126 reads (14%) | catalogued as COSV57837183; called by muse, mutect2, varscan2
- CYP3A43 | c.746T>A p.L249* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as rs759645964, COSV55935344; called by muse, mutect2, varscan2
- CYP4F2 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs750598459, COSV50000283; called by muse, mutect2, varscan2
- DAB2IP | c.1130C>G p.S377C (on ENST00000408936; = p.S349C on NM_032552.3) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV52257626; called by muse, mutect2, varscan2
- DCHS1 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761959340, COSV55034071; called by muse, mutect2, varscan2
- DCP1B | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV54968443; called by muse, mutect2, varscan2
- DCP2 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV66616763; called by muse, mutect2, varscan2
- DDIAS | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs761510889, COSV61271890; called by muse, mutect2, varscan2
- DDX10 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59432122; called by muse, varscan2
- DDX54 | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.388); catalogued as COSV58372968; called by muse, mutect2, varscan2
- DEK | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV55237192; called by muse, mutect2, varscan2
- DENND4C | c.3228G>C p.K1076N (on ENST00000434457 / NM_001330640.2; = p.K1027N on NM_017925.7) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV63008650; called by muse, mutect2, varscan2
- DENND4C | c.3690G>C p.K1230N (on ENST00000434457 / NM_001330640.2; = p.K1181N on NM_017925.7) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV63008651; called by muse, mutect2, varscan2
- DGKD | c.550C>G p.L184V (on ENST00000264057 / NM_152879.3; = p.L140V on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV51040376; called by muse, mutect2, varscan2
- DGKE | c.1623G>A p.M541I | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52349462; called by muse, mutect2, varscan2
- DHX36 | c.2108G>A p.G703E | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57671901; called by muse, mutect2, varscan2
- DIDO1 | c.3192G>C p.Q1064H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV56612735, COSV56619227; called by muse, mutect2, varscan2
- DISP1 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs758163679, COSV52654961; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP2 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.653); catalogued as COSV51119322; called by muse, mutect2, varscan2
- DLEC1 | c.4025C>T p.S1342F | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV57298291; called by muse, mutect2, varscan2
- DLG2 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54618835, COSV54636335; called by muse, mutect2
- DLG2 | c.1932C>G p.F644L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV54636376, COSV99720783; called by muse, mutect2, varscan2
- DLGAP3 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1326461735, COSV52393227; called by muse, mutect2, varscan2
- DMRT3 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1261539213, COSV51903809; called by muse, mutect2, varscan2
- DMWD | c.558C>G p.F186L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV54288675; called by muse, varscan2
- DMXL1 | c.4867G>C p.E1623Q | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60709186; called by muse, mutect2, varscan2
- DMXL2 | c.4790C>G p.S1597C | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51844431; called by muse, mutect2, varscan2
- DNAH11 | c.10468G>A p.E3490K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV60951665; called by muse, mutect2, varscan2
- DNAH17 | c.12895G>C p.D4299H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53144570; called by muse, mutect2, varscan2
- DNAH17 | c.5515C>G p.L1839V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101103216, COSV67752403; called by muse, mutect2, varscan2
- DNAH2 | c.11909C>T p.S3970F | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV66718536; called by muse, mutect2, varscan2
- DNAI1 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54280364, COSV54280621; called by muse, varscan2
- DNAJC11 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53785811; called by muse, mutect2, varscan2
- DNMT3A | c.2640G>A p.M880I | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV53047744, COSV53050507, COSV53067294; called by muse, mutect2, varscan2
- DNTT | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64522886; called by muse, mutect2, varscan2
- DOCK10 | c.4334G>A p.R1445Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as rs759282940, COSV51356197; called by muse, varscan2
- DOK7 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs777986024; called by muse, mutect2
- DOP1B | c.3313G>C p.D1105H | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV67692952; called by muse, mutect2, varscan2
- DOP1B | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV67692956; called by muse, mutect2, varscan2
- DOP1B | c.4419G>C p.Q1473H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as COSV67692948, COSV67692962, COSV67693049; called by muse, mutect2, varscan2
- DOP1B | c.4973C>G p.S1658C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67692459; called by muse, mutect2, varscan2
- DPYD | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64595008; called by muse, mutect2, varscan2
- DSC1 | c.1465G>C p.E489Q | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.11); catalogued as COSV57144281, COSV57152215; called by muse, varscan2
- DSCAM | c.2506C>G p.L836V | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV68025003; called by muse, mutect2, varscan2
- DSCAML1 | c.4456G>C p.E1486Q (on ENST00000321322; = p.E1426Q on NM_020693.4) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58388117; called by muse, mutect2, varscan2
- DSG1 | c.1075C>A p.H359N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV57134582, COSV57135087; called by muse, mutect2, varscan2
- DSG1 | c.1701G>C p.L567F | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57134594; called by muse, varscan2
- DSG1 | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57134604; called by muse, varscan2
- DST | c.1186G>A p.D396N (on ENST00000361203 / NM_001374722.1; = p.D70N on NM_001723.6) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV55008739; called by muse, mutect2, varscan2
- DTL | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.024); catalogued as rs766296682, COSV65342033; called by muse, mutect2, varscan2
- DUT | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV58664240, COSV58664529; called by muse, mutect2
- DYSF | c.4609G>C p.E1537Q | Missense Mutation (SNP) | VAF 80/355 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV50295401, COSV50314212; called by muse, mutect2, varscan2
- DZIP3 | c.2204C>T p.S735L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as rs139764708; called by muse, mutect2, varscan2
- DZIP3 | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV64311720; called by muse, mutect2, varscan2
- EEF1A2 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV53205678, COSV53206912; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV66964530; called by muse, mutect2, varscan2
- EFCAB5 | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.187); catalogued as COSV57928353; called by muse, mutect2, varscan2
- EGF | c.3619C>G p.Q1207E | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV54477664; called by muse, mutect2, varscan2
- EGFR | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as COSV51790783; called by muse, mutect2, varscan2
- ELOA2 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1569056446, COSV55297268; called by muse, mutect2, varscan2
- ELOVL6 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56428247; called by muse, mutect2, varscan2
- EMC7 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV56627494; called by mutect2, varscan2
- EMILIN2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV54422716; called by muse, mutect2, varscan2
- EML1 | c.2192-1G>T p.X731_splice | Splice Site (SNP) | VAF 18/100 reads (18%) | catalogued as COSV51743655; called by muse, mutect2, varscan2
- EML1 | c.2298C>G p.F766L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV51742244; called by muse, mutect2, varscan2
- EP300 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV54339220; called by muse, mutect2, varscan2
- EP300 | c.2905G>T p.E969* | Nonsense Mutation (SNP) | VAF 27/129 reads (21%) | catalogued as COSV99607864; called by muse, mutect2, varscan2
- EP300 | c.5433G>T p.Q1811H | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54330772; called by muse, mutect2, varscan2
- EPB41L3 | c.2473-1G>C p.X825_splice | Splice Site (SNP) | VAF 26/121 reads (21%) | catalogued as rs775996479, COSV59450255; called by muse, mutect2, varscan2
- EPC1 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV53924903; called by muse, mutect2, varscan2
- EPHA5 | c.2260G>C p.E754Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56640093; called by muse, mutect2, varscan2
- EPHA5 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV56628603; called by muse, mutect2, varscan2
- ERAP2 | c.1621T>G p.W541G | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65939395; called by muse, mutect2, varscan2
- ERMAP | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as COSV60274028; called by muse, mutect2, varscan2
- ERN2 | c.2153C>G p.S718C | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55621469; called by muse, mutect2, varscan2
- ESD | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV66339989; called by muse, mutect2, varscan2
- ETV6 | c.464-1G>T p.X155_splice | Splice Site (SNP) | VAF 42/174 reads (24%) | catalogued as COSV67149257, COSV67153384; called by muse, mutect2, varscan2
- EVI5 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.05); catalogued as COSV64826493; called by muse, mutect2, varscan2
- EXPH5 | c.3707C>T p.S1236F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56201051; called by muse, mutect2, varscan2
- F13A1 | c.1921C>T p.Q641* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as CM161517; called by muse, mutect2
- F5 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63122914; called by muse, mutect2, varscan2
- FAT4 | c.889C>G p.Q297E | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.069); catalogued as COSV67884231; called by muse, mutect2, varscan2
- FAT4 | c.8435C>G p.S2812C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV58679915; called by muse, mutect2, varscan2
- FBF1 | c.1087G>C p.E363Q (on ENST00000586717; = p.E377Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV59864439; called by muse, mutect2, varscan2
- FBXL12 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as rs370622099, COSV56113982; called by muse, mutect2
- FBXL13 | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV57536952; called by muse, varscan2
- FBXO17 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV53069430, COSV99493865; called by muse, mutect2, varscan2
- FBXO22 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.003); catalogued as COSV51192639; called by muse, mutect2, varscan2
- FBXO28 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV64800150; called by muse, varscan2
- FBXO28 | c.998G>C p.G333A | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as COSV64800155; called by muse, varscan2
- FBXO3 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV55765851; called by muse, mutect2, varscan2
- FBXO39 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV58621564; called by muse, mutect2, varscan2
- FBXW4 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV58707480; called by muse, mutect2, varscan2
- FBXW9 | c.331C>G p.R111G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV63508032; called by muse, mutect2, varscan2
- FER1L6 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV67551514; called by muse, mutect2, varscan2
- FGF10 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs775259892, COSV52931887, COSV52934040; called by muse, mutect2, varscan2
- FGFR1 | c.933G>C p.L311F (on ENST00000447712 / NM_023110.3; = p.L309F on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV58332504; called by muse, mutect2, varscan2
- FGGY | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV58031098; called by muse, mutect2, varscan2
- FILIP1 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52727266; called by muse, mutect2, varscan2
- FILIP1 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52727281; called by muse, mutect2, varscan2
- FIP1L1 | c.1159C>G p.L387V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); catalogued as COSV60995546; called by muse, mutect2, varscan2
- FKBP15 | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.345); catalogued as COSV53033720; called by muse, mutect2, varscan2
- FLG | c.3913G>A p.G1305S | Missense Mutation (SNP) | VAF 81/333 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.014); catalogued as rs764258832, COSV64240256; called by muse, mutect2, varscan2
- FMNL2 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.093); catalogued as COSV56493322; called by muse, mutect2, varscan2
- FMR1NB | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 30/60 reads (50%) | catalogued as COSV63272999; called by muse, mutect2, varscan2
- FNDC3A | c.529G>C p.E177Q (on ENST00000492622 / NM_001079673.2; = p.E121Q on NM_014923.5) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV101001369, COSV65695233; called by muse, mutect2, varscan2
- FSTL4 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54768190, COSV54769302; called by muse, mutect2, varscan2
- FTSJ3 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as COSV59562044; called by muse, mutect2, varscan2
- FYB1 | c.519G>C p.L173F | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as COSV60944684; called by muse, mutect2, varscan2
- FZR1 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV58051288; called by muse, mutect2, varscan2
- GABRA3 | c.977G>T p.R326I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100942747, COSV64797557; called by muse, mutect2, varscan2
- GABRA4 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1475507683, COSV51926028; called by muse, mutect2, varscan2
- GALNT2 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV64194360; called by muse, varscan2
- GALNT6 | c.226C>G p.P76A | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200846978, COSV62541979; called by muse, mutect2, varscan2
- GANAB | c.1629G>A p.M543I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60463855; called by muse, mutect2, varscan2
- GC | c.56G>C p.R19T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV56736805; called by muse, mutect2, varscan2
- GCH1 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV54301668; called by muse, mutect2, varscan2
- GCM2 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 88/164 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs763269716, COSV65275408; called by muse, mutect2, varscan2
- GDA | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV52992005, COSV52999666; called by muse, mutect2, varscan2
- GET4 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.331); catalogued as COSV56254203; called by muse, mutect2, varscan2
- GGT7 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as COSV60540464; called by muse, mutect2, varscan2
- GGT7 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60540477, COSV60540922; called by muse, mutect2, varscan2
- GIPC3 | c.936G>C p.Q312H (on ENST00000644946; = p.R308T on NM_133261.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1199684186; called by muse, mutect2
- GK2 | c.1130G>C p.R377T | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62626525; called by muse, mutect2, varscan2
- GLI2 | c.1615C>G p.R539G (on ENST00000361492 / NM_001374353.1; = p.R556G on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58034512, COSV58039499; called by muse, mutect2, varscan2
- GLRX3 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV58691687, COSV58692231; called by muse, mutect2, varscan2
- GLT6D1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as rs778745771, COSV65626983; called by muse, mutect2, varscan2
- GLUD1 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV53278203; called by muse, mutect2, varscan2
- GLYAT | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV53539018; called by muse, mutect2, varscan2
- GNB5 | c.1132G>A p.D378N (on ENST00000261837 / NM_016194.4; = p.D336N on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs372011977, COSV55898056; called by muse, mutect2, varscan2
- GOLGA2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV70168241; called by muse, mutect2, varscan2
- GORASP2 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV52201556; called by muse, mutect2, varscan2
- GP6 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV59977043; called by muse, mutect2, varscan2
- GPATCH2L | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV55047896; called by muse, mutect2, varscan2
- GPR37L1 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66162119; called by muse, mutect2, varscan2
- GPR84 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV57209296, COSV57209477; called by muse, mutect2, varscan2
- GRAMD1C | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV63982485; called by muse, mutect2, varscan2
- GRIN1 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV59294534; called by muse, mutect2
- GRIN2B | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.042); catalogued as COSV101663184, COSV74205547; called by muse, mutect2, varscan2
- GRIN2D | c.1025C>G p.P342R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54378165; called by muse, mutect2, varscan2
- GRINA | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57592520; called by muse, mutect2, varscan2
- GSX1 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV57232734; called by muse, mutect2, varscan2
- GTF3C1 | c.753G>A p.R251= | Splice Region (SNP) | VAF 22/82 reads (27%) | catalogued as COSV62240351; called by muse, mutect2, varscan2
- GTF3C4 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV64645191; called by muse, mutect2, varscan2
- GTPBP2 | c.1174C>A p.L392M | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV61075996, COSV61076035; called by muse, mutect2, varscan2
- GUCY1A2 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs761503334, COSV56484019, COSV99977416; called by muse, mutect2, varscan2
- H2AC8 | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV55126469, COSV55126575; called by muse, mutect2, varscan2
- H3C2 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV52518397, COSV52518528; called by muse, mutect2, varscan2
- H4C13 | c.311G>T p.*104Lext*? | Nonstop Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as rs1020190776, COSV100138001, COSV60695004; called by muse, mutect2, varscan2
- H4C8 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.7); catalogued as rs780851749, COSV56804907; called by muse, mutect2, varscan2
- HCLS1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780143738, COSV58855664; called by muse, mutect2, varscan2
- HECA | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62769019; called by muse, mutect2, varscan2
- HECW2 | c.2986G>A p.D996N | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53656160; called by muse, mutect2, varscan2
- HELB | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV56073346; called by muse, mutect2, varscan2
- HEPH | c.154C>G p.L52V (on ENST00000343002; = p.L106V on NM_138737.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV57961926; called by muse, mutect2, varscan2
- HERC1 | c.13334C>A p.P4445H | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV71247211; called by muse, varscan2
- HERPUD1 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.302); catalogued as COSV55861963; called by muse, mutect2, varscan2
- HES1 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51684428; called by muse, mutect2, varscan2
- HEXIM1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60176761; called by muse, mutect2, varscan2
- HKDC1 | c.1415G>A p.R472K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV63576550; called by muse, mutect2, varscan2
- HLA-A | c.180del p.F60Lfs*17 | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | catalogued as COSV65139538; called by mutect2, pindel, varscan2
- HLA-DQA2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV66565156; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.397G>C p.E133Q (on ENST00000354667 / NM_031243.3; = p.E121Q on NM_002137.4) | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV61158642; called by muse, varscan2
- HOOK2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as rs1324886275, COSV53402016, COSV99317763; called by muse, mutect2, varscan2
- HPS3 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV56053790; called by muse, mutect2, varscan2
- HRNR | c.5204C>G p.S1735* | Nonsense Mutation (SNP) | VAF 27/289 reads (9%) | catalogued as rs1313192740; called by muse, mutect2, varscan2
- HS3ST5 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100450809, COSV57138489; called by muse, mutect2, varscan2
- HSD17B8 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1266151086, COSV63002464; called by muse, mutect2, varscan2
- HSF5 | c.1358C>G p.S453C | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV60416214, COSV60418163; called by muse, mutect2, varscan2
- HSPD1 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV104421388, COSV61444212; called by muse, mutect2, varscan2
- HTR3E | c.781C>G p.L261V (on ENST00000415389 / NM_001256613.1; = p.L276V on NM_182589.2) | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58946434, COSV58949251; called by muse, mutect2, varscan2
- HTRA3 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745448154, COSV56470594; called by muse, mutect2, varscan2
- HYDIN | c.6819G>A p.M2273I | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV59254792; called by muse, mutect2, varscan2
- IFT172 | c.3917G>C p.G1306A | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV53132431; called by muse, mutect2, varscan2
- IGFL1 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV71443594, COSV71443610; called by muse, mutect2, varscan2
- IGSF10 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 80/339 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV56783993; called by muse, mutect2, varscan2
- IL31RA | c.1641C>T p.F547= | Splice Region (SNP) | VAF 35/147 reads (24%) | catalogued as COSV51681125; called by muse, mutect2, varscan2
- IL37 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs532660211, COSV54490741; called by muse, mutect2, varscan2
- IL6ST | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV61140804; called by muse, mutect2, varscan2
- INA | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1282165523, COSV63975854; called by muse, mutect2, varscan2
- INCA1 | c.635C>T p.S212L (on ENST00000574617 / NM_001167986.1; = p.S197L on NM_213726.2) | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV61788308; called by muse, mutect2, varscan2
- INO80D | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68958651; called by muse, mutect2, varscan2
- INTS13 | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); catalogued as COSV53902176; called by muse, mutect2, varscan2
- INTS7 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.398); catalogued as COSV65344108; called by muse, mutect2, varscan2
- INTS9 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV68433843, COSV68435723; called by muse, mutect2, varscan2
- IQCB1 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1473351493, COSV60436991; called by muse, varscan2
- IQCB1 | c.27G>T p.R9S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60436997; called by muse, varscan2
- IQCC | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs368831638; called by muse, mutect2, varscan2
- IQCC | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV52208518; called by muse, mutect2, varscan2
- IRX4 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1048121863, COSV51471995; called by muse, mutect2, varscan2
- ITGAM | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54936159; called by muse, mutect2, varscan2
- ITGB1BP1 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as rs201269168, COSV53005854, COSV53006084; called by muse, mutect2, varscan2
- ITPKC | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54574230; called by muse, mutect2, varscan2
- ITSN2 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as COSV61945698; called by muse, mutect2, varscan2
- IWS1 | c.1631G>A p.R544K | Missense Mutation (SNP) | VAF 83/364 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV54867818; called by muse, mutect2, varscan2
- JAK2 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); catalogued as rs1351891082, COSV67601003; called by muse, mutect2, varscan2
- JMJD1C | c.5920C>T p.Q1974* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100550915; called by muse, mutect2, varscan2
- KBTBD2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV58363268; called by muse, mutect2, varscan2
- KBTBD8 | c.225C>T p.F75= | Splice Region (SNP) | VAF 32/137 reads (23%) | catalogued as COSV55128032; called by muse, varscan2
- KCNB2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73049756; called by muse, mutect2, varscan2
- KCNE2 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV51710158; called by muse, mutect2, varscan2
- KCNH7 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as rs1232302531, COSV59788219; called by muse, mutect2, varscan2
- KCNN4 | c.975C>G p.F325L | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53455244; called by muse, mutect2, varscan2
- KCNRG | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV53948944; called by muse, mutect2, varscan2
- KHDRBS1 | c.1307G>C p.R436T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56981701; called by muse, mutect2, varscan2
- KIAA1109 | c.10642G>A p.E3548K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52669050; called by muse, mutect2, varscan2
- KIAA1328 | c.122C>G p.S41* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as COSV54447437; called by muse, mutect2, varscan2
- KIF19 | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV63429250; called by muse, mutect2
- KIF20B | c.5069C>T p.S1690F (on ENST00000371728 / NM_001284259.2; = p.S1650F on NM_016195.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV53305557; called by muse, mutect2, varscan2
- KIF26B | c.1388G>C p.R463P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.115); catalogued as COSV63650518; called by muse, mutect2
- KIF27 | c.3003G>C p.K1001N | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52826949; called by muse, mutect2, varscan2
- KIF6 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.164); catalogued as COSV54674181, COSV54684039; called by muse, mutect2, varscan2
- KLHDC8B | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60411641; called by muse, mutect2, varscan2
- KLHL1 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.021); catalogued as rs780858672, COSV64770502; called by muse, mutect2, varscan2
- KLHL18 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV51745046; called by muse, mutect2, varscan2
- KLHL23 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55866688; called by muse, mutect2, varscan2
- KMT2B | c.5435C>G p.S1812* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99719106; called by muse, varscan2
- KMT2C | c.10960C>T p.Q3654* | Nonsense Mutation (SNP) | VAF 38/145 reads (26%) | catalogued as COSV100069245; called by muse, mutect2, varscan2
- KMT2C | c.3757G>T p.E1253* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100068708, COSV100069249; called by muse, mutect2, varscan2
- KMT2D | c.11050C>T p.Q3684* | Nonsense Mutation (SNP) | VAF 36/157 reads (23%) | catalogued as COSV99978899; called by muse, mutect2, varscan2
- KRTAP10-9 | c.140G>A p.C47Y | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs587734825, COSV59958461; called by muse, mutect2, varscan2
- LAMA2 | c.3571G>A p.E1191K | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.416); catalogued as COSV70344499, COSV70351713; called by muse, mutect2, varscan2
- LAMA3 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58066775; called by muse, mutect2, varscan2
- LAMB2 | c.4093C>T p.R1365W | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751854328, COSV59732648; called by muse, mutect2, varscan2
- LAMB3 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.601); catalogued as COSV61916304; called by muse, mutect2, varscan2
- LAMC3 | c.3406C>T p.L1136F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1264469858, COSV63088440; called by muse, mutect2
- LAPTM5 | c.600C>G p.I200M | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV53853014; called by muse, mutect2, varscan2
- LARP1 | c.1744C>G p.L582V (on ENST00000518297 / NM_033551.3; = p.L505V on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60426261; called by muse, mutect2, varscan2
- LARP4B | c.1810C>T p.H604Y | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV60221036; called by muse, mutect2, varscan2
- LCOR | c.4420G>C p.E1474Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV53715360; called by muse, mutect2, varscan2
- LGI4 | c.1600G>C p.D534H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59533217, COSV59533385; called by muse, mutect2, varscan2
- LINGO3 | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV68261179; called by muse, mutect2, varscan2
- LMAN2L | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV53841399; called by muse, mutect2, varscan2
- LMO7 | c.3268G>A p.E1090K (on ENST00000357063; = p.E771K on NM_005358.5) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.073); catalogued as COSV58533748; called by muse, mutect2, varscan2
- LONP1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs919262130, COSV100638753, COSV62261345; called by muse, mutect2, varscan2
- LPA | c.3572C>T p.S1191F | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs770246075, COSV60300391; called by muse, mutect2, varscan2
- LRP4 | c.2359G>A p.V787M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as rs368412829; called by muse, mutect2, varscan2
- LRR1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as rs1380598577, COSV53563165; called by muse, mutect2, varscan2
- LRRC30 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.185); catalogued as COSV67301587; called by muse, mutect2, varscan2
- LRRFIP2 | c.1654C>G p.Q552E | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV60867158; called by muse, mutect2, varscan2
- LYAR | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.652); catalogued as COSV58642601; called by muse, mutect2, varscan2
- MAEA | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV53262053; called by muse, mutect2, varscan2
- MAGEL2 | c.3560G>A p.R1187Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.427); catalogued as COSV58566629; called by muse, mutect2, varscan2
- MAGI1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV58322183; called by muse, mutect2, varscan2
- MAGI3 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100290255; called by muse, mutect2, varscan2
- MAML2 | c.705G>C p.M235I | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV73263187, COSV73264236; called by muse, mutect2, varscan2
- MAML3 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV59073114; called by muse, mutect2, varscan2
- MAN1A1 | c.506G>C p.R169T | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as COSV63782187; called by muse, mutect2, varscan2
- MANBAL | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs766095592, COSV65311445, COSV65311923; called by muse, mutect2, varscan2
- MAP2K4 | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100796472, COSV62256562; called by muse, mutect2, varscan2
- MAP3K13 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.05); catalogued as COSV53986963; called by muse, mutect2, varscan2
- MAP3K6 | c.3313G>T p.D1105Y | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58871257; called by muse, mutect2, varscan2
- MAP7 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63418932; called by muse, mutect2, varscan2
- MAP7D1 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60215915; called by muse, mutect2, varscan2
- MARCHF7 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.091); catalogued as rs372655786; called by muse, mutect2, varscan2
- MARK2 | c.1582C>T p.R528C (on ENST00000402010 / NM_001039469.2; = p.R494C on NM_017490.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs972173237, COSV59282370; called by mutect2, varscan2
- MAST3 | c.1127G>C p.G376A | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53219552; called by muse, mutect2, varscan2
- MASTL | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.036); catalogued as COSV60910405; called by muse, mutect2, varscan2
- MAT2A | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV52087861; called by muse, mutect2, varscan2
- MAT2A | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.903); catalogued as COSV52087869; called by muse, mutect2, varscan2
- MATK | c.1012G>C p.E338Q (on ENST00000310132 / NM_139355.3; = p.E339Q on NM_002378.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as rs760149262, COSV59554117; called by muse, mutect2, varscan2
- MATR3 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV63076866; called by muse, mutect2, varscan2
- MBTD1 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs776267329, COSV64503191; called by muse, mutect2, varscan2
- MBTPS1 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs575732938, COSV58570290; called by muse, mutect2, varscan2
- MCRS1 | c.1356C>G p.I452M | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV57790355; called by muse, mutect2, varscan2
- MDFIC | c.512T>C p.I171T | Missense Mutation (SNP) | VAF 104/444 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57563181; called by muse, mutect2, varscan2
- MED1 | c.3680C>T p.S1227L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs144178898; called by muse, mutect2, varscan2
- MED12 | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV61336067; called by muse, mutect2, varscan2
- MED13 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV67262996; called by muse, mutect2, varscan2
- MED22 | c.111C>G p.I37M | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV59297875; called by muse, varscan2
- MEGF9 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as COSV64235170; called by muse, mutect2, varscan2
- MFSD12 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV62597524; called by muse, mutect2, varscan2
- MGAM | c.639G>C p.L213F | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.075); catalogued as COSV71885292; called by muse, mutect2, varscan2
- MGAT1 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | PolyPhen probably damaging (0.925); catalogued as COSV57133832; called by muse, mutect2, varscan2
- MGAT4C | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59830124, COSV59831777; called by muse, mutect2, varscan2
- MIB1 | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV55089589; called by muse, varscan2
- MIB2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV61755533; called by muse, mutect2
- MICAL1 | c.1107G>C p.M369I | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV62193018, COSV62194591; called by muse, mutect2, varscan2
- MICAL2 | c.1492C>T p.L498F | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV56319305; called by muse, mutect2, varscan2
- MIDEAS | c.1642G>C p.D548H | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.417); catalogued as COSV54094094; called by muse, mutect2, varscan2
- MIDEAS | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54094101, COSV99679153; called by muse, mutect2, varscan2
- MIPOL1 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV59382560; called by muse, mutect2, varscan2
- MIS18A | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV51589038; called by muse, mutect2, varscan2
- MLEC | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV57329423; called by muse, mutect2, varscan2
- MME | c.1357C>G p.Q453E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64706860; called by muse, mutect2, varscan2
- MOV10 | c.2580G>C p.L860F | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV53517213; called by muse, mutect2, varscan2
- MOV10 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747208248, COSV53517225; called by muse, varscan2
- MPO | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56561478, COSV56563007; called by muse, mutect2, varscan2
- MPPE1 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100013128; called by muse, mutect2, varscan2
- MRPS30 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50181617; called by muse, mutect2, varscan2
- MRPS7 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1484684294, COSV55453267; called by muse, mutect2, varscan2
- MSANTD4 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs778128744, COSV57285620; called by muse, mutect2, varscan2
- MTM1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782709837, COSV60334599; called by muse, mutect2, varscan2
- MTMR10 | c.1525C>T p.H509Y | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.469); catalogued as COSV58727866; called by muse, mutect2, varscan2
- MTMR2 | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60579296; called by muse, mutect2, varscan2
- MUC15 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV55553923, COSV55553994; called by muse, mutect2, varscan2
- MUC16 | c.15796G>A p.E5266K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs772876704, COSV67452529; called by muse, mutect2, varscan2
- MUC16 | c.8273C>T p.S2758F | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV67448876; called by muse, mutect2, varscan2
- MUC3A | c.7031C>A p.S2344* | Nonsense Mutation (SNP) | VAF 58/283 reads (20%) | catalogued as rs779034557; called by muse, mutect2, varscan2
- MUC5AC | c.15723C>T p.L5241= | Splice Region (SNP) | VAF 40/160 reads (25%) | catalogued as rs773274173, COSV64369312; called by muse, varscan2
- MYCBP2 | c.6451G>C p.D2151H (on ENST00000357337; = p.D2189H on NM_015057.5) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62015396; called by muse, mutect2, varscan2
- MYCBPAP | c.1258-1G>A p.X420_splice | Splice Site (SNP) | VAF 21/99 reads (21%) | catalogued as rs56367701, COSV60406721; called by muse, mutect2, varscan2
- MYH6 | c.2569G>C p.E857Q | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62449450; called by muse, mutect2, varscan2
- MYH9 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53384760; called by muse, mutect2
- MYO18B | c.2203C>G p.Q735E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as COSV59131305; called by mutect2, varscan2
- MYO1E | c.2239G>C p.G747R | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55685371; called by muse, mutect2, varscan2
- MYPN | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as COSV62735421; called by muse, mutect2, varscan2
- MYT1L | c.3492G>C p.Q1164H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs913314468, COSV67702036; called by muse, mutect2, varscan2
- NAA15 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV56719055; called by muse, mutect2, varscan2
- NAALADL1 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV60523517; called by muse, mutect2, varscan2
- NALCN | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.219); catalogued as COSV51929360, COSV51952313; called by muse, mutect2, varscan2
- NAV2 | c.4952C>T p.S1651L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60658413; called by muse, mutect2, varscan2
- NAV3 | c.5068G>C p.D1690H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57074159, COSV57084008; called by muse, mutect2, varscan2
- NBEAL1 | c.4498G>C p.E1500Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV71374122; called by muse, mutect2, varscan2
- NCBP1 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1217182356, COSV64316635; called by muse, mutect2, varscan2
- NCOA1 | c.1555G>A p.V519I | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs144856306; called by muse, mutect2, varscan2
- NCSTN | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV54186926; called by muse, mutect2, varscan2
- NDUFA7 | c.102-1G>T p.X34_splice | Splice Site (SNP) | VAF 26/125 reads (21%) | catalogued as rs764308196, COSV56846343; called by muse, mutect2, varscan2
- NDUFV1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as rs769368657, COSV59595159; called by muse, mutect2, varscan2
- NEB | c.10942G>C p.E3648Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.668); catalogued as COSV50806523, COSV51105195; called by muse, mutect2, varscan2
- NEFL | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55336747, COSV99648217; called by muse, mutect2, varscan2
- NEFM | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs368542205; called by muse, mutect2
- NEK9 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV53130558; called by muse, mutect2, varscan2
- NFS1 | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65053694; called by muse, mutect2, varscan2
- NFS1 | c.968C>G p.S323* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100931885; called by muse, mutect2, varscan2
- NHEJ1 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55406434; called by muse, mutect2, varscan2
- NIF3L1 | c.967G>A p.D323N (on ENST00000409020 / NM_001369444.1; = p.D296N on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.435); catalogued as rs569758765, COSV62900131; called by muse, mutect2, varscan2
- NKIRAS2 | c.395C>G p.P132R | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56917694; called by muse, mutect2, varscan2
- NLRP5 | c.1435G>T p.V479L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.212); catalogued as COSV66763712; called by muse, mutect2, varscan2
- NNMT | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs768238759, COSV55473505; called by muse, mutect2, varscan2
- NOS1AP | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV62633932; called by muse, mutect2, varscan2
- NOTCH1 | c.5567C>T p.S1856F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV53043799, COSV53053754; called by muse, mutect2, varscan2
- NPC1L1 | c.1659C>A p.F553L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV56924095; called by muse, mutect2, varscan2
- NPHS2 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as CM141332; called by muse, mutect2, varscan2
- NPHS2 | c.537C>T p.I179= | Splice Region (SNP) | VAF 13/51 reads (25%) | catalogued as rs370260554; called by muse, mutect2, varscan2
- NRDC | c.3016G>C p.E1006Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61403600; called by muse, mutect2, varscan2
- NTN1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51480615; called by muse, mutect2, varscan2
- NUAK2 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV65681233; called by muse, mutect2, varscan2
- NUP85 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1350790812, COSV55463908; called by muse, mutect2
- NUTF2 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV54645735; called by muse, varscan2
- NYAP1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs755139687, COSV55718323; called by muse, mutect2, varscan2
- NYAP1 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.292); catalogued as rs376633711; called by muse, mutect2, varscan2
- OASL | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV57477946; called by muse, mutect2, varscan2
- OBSCN | c.9875C>T p.T3292M | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.835); catalogued as rs560187892, COSV52763153; called by muse, mutect2, varscan2
- ODF2 | c.1990C>G p.L664V (on ENST00000434106 / NM_153433.2; = p.L640V on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV63546550; called by muse, mutect2, varscan2
- OGFOD1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 45/239 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as COSV55859729; called by muse, mutect2, varscan2
- OPRD1 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV52381591, COSV99330274; called by muse, mutect2, varscan2
- OR1J2 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); catalogued as COSV58944154; called by muse, mutect2
- OR2T8 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60662839, COSV60664665; called by muse, mutect2, varscan2
- OR4C15 | c.215A>T p.N72I (on ENST00000314644; = p.N18I on NM_001001920.2) | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV58952232; called by muse, mutect2, varscan2
- OR4C16 | c.626A>C p.Y209S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV58941526; called by muse, mutect2, varscan2
- OR4K2 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 37/451 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100064012, COSV53849078, COSV53849409; called by muse, mutect2
- OR4K2 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53849090, COSV53849677; called by muse, mutect2, varscan2
- OR51D1 | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.534); catalogued as COSV62914077; called by muse, mutect2, varscan2
- OR52D1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100495321, COSV59487307; called by muse, mutect2, varscan2
- OR6B3 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); catalogued as COSV60113609; called by muse, mutect2, varscan2
- OR6C74 | c.539C>G p.S180C | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as COSV59606118; called by muse, mutect2, varscan2
- OR7D2 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as rs752945531, COSV60139518; called by muse, mutect2
- ORM1 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.909); catalogued as rs143596557; called by muse, mutect2, varscan2
- OSBP2 | c.2644G>C p.E882Q | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as rs1282874190; called by muse, mutect2, varscan2
- OTUD4 | c.688G>A p.E230K (on ENST00000447906 / NM_001366057.1; = p.E165K on NM_001102653.1) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs767841072, COSV56850370; called by muse, mutect2, varscan2
- PAFAH1B1 | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV68210157; called by muse, varscan2
- PAN2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV57753455; called by muse, mutect2, varscan2
- PARP6 | c.150C>G p.I50M | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV53002786; called by muse, mutect2, varscan2
- PARVB | c.75G>T p.R25S | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV100601486, COSV63109708; called by muse, mutect2
- PAXBP1 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51608277; called by muse, mutect2, varscan2
- PBRM1 | c.3145G>A p.E1049K (on ENST00000296302 / NM_001366071.2; = p.E1024K on NM_018313.5) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV56263028, COSV56270863; called by muse, mutect2, varscan2
- PBRM1 | c.2966-1G>C p.X989_splice | Splice Site (SNP) | VAF 12/71 reads (17%) | catalogued as COSV56270893, COSV56302997; called by muse, mutect2, varscan2
- PBX1 | c.610A>C p.I204L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV63342960; called by muse, mutect2, varscan2
- PCDHA1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV65373234; called by muse, mutect2, varscan2
- PCDHA11 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 69/337 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs950790626, COSV56493380; called by muse, mutect2, varscan2
- PCDHB15 | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV50889694, COSV50909484; called by muse, mutect2, varscan2
- PCDHB8 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.04); catalogued as COSV50761782; called by muse, mutect2, varscan2
- PCDHGC3 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52749129; called by muse, mutect2, varscan2
- PCNT | c.8248G>C p.E2750Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.863); catalogued as COSV100854981, COSV64027141; called by muse, mutect2, varscan2
- PCNX2 | c.2843C>T p.S948L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV50793142; called by muse, mutect2, varscan2
- PDE12 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV60818495; called by muse, mutect2, varscan2
- PDE2A | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57805162; called by muse, mutect2, varscan2
- PDE9A | c.1748G>C p.R583T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV52324818; called by muse, mutect2, varscan2
- PDZD8 | c.2029C>G p.Q677E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV57824798; called by muse, mutect2, varscan2
- PEG3 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1341905698, COSV55630625; called by muse, mutect2, varscan2
- PELP1 | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.984); catalogued as rs752579746; called by muse, mutect2, varscan2
- PEX5L | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV55853442; called by muse, mutect2, varscan2
- PEX6 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV55102725; called by muse, mutect2, varscan2
- PFDN2 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV63509496; called by muse, mutect2, varscan2
- PGC | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV57824494; called by muse, mutect2, varscan2
- PGR | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV54799788; called by muse, mutect2, varscan2
- PHACTR3 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as COSV63026877; called by muse, mutect2, varscan2
- PHETA1 | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1216618621; called by muse, mutect2, varscan2
- PHKA1 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59804707; called by muse, mutect2, varscan2
- PIK3R4 | c.51G>C p.E17D | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs143147652; called by muse, mutect2, varscan2
- PIKFYVE | c.4657C>T p.Q1553* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as rs779619230; called by muse, mutect2, varscan2
- PITRM1 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs757249239; called by muse, mutect2
- PLEC | c.3169G>C p.E1057Q (on ENST00000322810 / NM_201380.4; = p.E947Q on NM_000445.5) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as COSV100513241, COSV59625166; called by muse, mutect2, varscan2
- PMEL | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59385600; called by muse, mutect2, varscan2
- PNLIPRP1 | c.447G>C p.Q149H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV62611453; called by muse, mutect2, varscan2
- PNPLA7 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52997456; called by muse, mutect2, varscan2
- PODN | c.561G>C p.E187D (on ENST00000395871; = p.E139D on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57012610; called by muse, mutect2, varscan2
- POLH | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771984623, COSV64779285; called by muse, mutect2, varscan2
- POLR1E | c.958G>A p.E320K (on ENST00000377792 / NM_001282766.1; = p.E258K on NM_022490.4) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as COSV66771920; called by muse, mutect2, varscan2
- POMT2 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV55070607; called by muse, mutect2, varscan2
- PON1 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV55931453; called by muse, varscan2
- PPL | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV62046161; called by muse, mutect2, varscan2
- PPM1A | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100348961, COSV57786430; called by muse, mutect2, varscan2
- PPP2R2B | c.1184T>G p.V395G (on ENST00000394409; = p.V461G on NM_181674.2) | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs778098894, COSV60751353; called by muse, mutect2, varscan2
- PPP2R3A | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV104369236, COSV53862426; called by muse, mutect2, varscan2
- PPWD1 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV54333347; called by muse, mutect2, varscan2
- PRAG1 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV58159479; called by muse, mutect2, varscan2
- PRDM16 | c.3538G>T p.E1180* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | catalogued as COSV99577140; called by muse, mutect2, varscan2
- PRDM2 | c.3158C>T p.S1053F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs756295414, COSV52445237; called by muse, varscan2
- PRDM2 | c.3194C>G p.S1065C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52445251; called by muse, varscan2
- PREP | c.571C>T p.P191S (on ENST00000369110; = p.P257S on NM_002726.5) | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV64869849; called by muse, varscan2
- PREX2 | c.3764C>T p.S1255L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV55759067, COSV55763573; called by muse, mutect2, varscan2
- PRKAR1A | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV62235425; called by muse, mutect2, varscan2
- PRKAR2A | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV55551634; called by muse, mutect2, varscan2
- PRKAR2A | c.143C>G p.S48* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV55553941; called by muse, mutect2, varscan2
- PRKCSH | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs142627856; called by muse, mutect2, varscan2
- PRKG2 | c.1665C>G p.F555L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52322726; called by muse, mutect2, varscan2
- PRMT7 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1217149803, COSV59832987; called by muse, mutect2, varscan2
- PSME4 | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.093); catalogued as COSV66364434; called by muse, mutect2, varscan2
- PTEN | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV100909805; called by muse, mutect2, varscan2
- PTGFRN | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV67798230; called by muse, varscan2
- PTPN13 | c.765C>G p.F255L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs997952042, COSV57405717; called by muse, mutect2, varscan2
- PTPN21 | c.2438C>G p.S813C | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV60847440; called by muse, mutect2, varscan2
- PTPN9 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV60723381, COSV60723402; called by muse, mutect2, varscan2
- PTPRD | c.3262C>T p.R1088C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs867884876, COSV61927895; called by muse, mutect2, varscan2
- PUM3 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV67396154; called by muse, mutect2, varscan2
- PWWP2B | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59449915; called by muse, mutect2, varscan2
- PYGM | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1048544068, COSV51215938; called by muse, mutect2, varscan2
- R3HCC1L | c.2058C>G p.F686L (on ENST00000612478 / NM_001256619.2; = p.F672L on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV54400526; called by muse, mutect2, varscan2
- RAB9B | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV54587152, COSV54587397, COSV99686092; called by muse, mutect2, varscan2
- RAD23B | c.915G>C p.Q305H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV63658159; called by muse, mutect2, varscan2
- RAD54L | c.165G>C p.L55F | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV64335856; called by muse, mutect2, varscan2
- RAG2 | c.1044G>C p.L348F | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57557237; called by muse, mutect2, varscan2
- RANBP2 | c.4768G>A p.E1590K | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV51698760; called by muse, mutect2, varscan2
- RAPH1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV57352336; called by muse, mutect2, varscan2
- RARB | c.526G>A p.E176K (on ENST00000383772 / NM_001290216.2; = p.E169K on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); catalogued as COSV58064757, COSV58066615; called by muse, mutect2, varscan2
- RASA2 | c.528C>T p.H176= | Splice Region (SNP) | VAF 18/86 reads (21%) | catalogued as COSV53938616; called by muse, mutect2, varscan2
- RB1CC1 | c.3836C>T p.S1279F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV50246047; called by muse, mutect2, varscan2
- RBAK | c.1026G>C p.E342D | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV62331223, COSV62331630; called by muse, mutect2, varscan2
- RBAK | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs760043040, COSV62330827, COSV62331233; called by muse, mutect2, varscan2
- RBBP4 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV65132403; called by muse, mutect2, varscan2
- RBM42 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.496); catalogued as rs1293905508, COSV52547487; called by muse, mutect2, varscan2
- RBMXL2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as rs1397269593, COSV60979380; called by muse, mutect2, varscan2
- RET | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60691486; called by muse, mutect2, varscan2
- RETREG2 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1211330271, COSV56087376; called by muse, mutect2, varscan2
- REV3L | c.8644G>C p.D2882H | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62617930; called by muse, mutect2, varscan2
- REXO1 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV50076669; called by muse, mutect2, varscan2
- RFC1 | c.1122G>C p.K374N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62899207; called by muse, mutect2, varscan2
- RICTOR | c.1222C>G p.L408V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57120532; called by muse, mutect2, varscan2
- RNF10 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs774559334, COSV58044582; called by muse, mutect2, varscan2
- RNF13 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV53523297; called by muse, mutect2, varscan2
- RNF168 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.122); catalogued as COSV58837321; called by muse, mutect2, varscan2
- ROBO1 | c.4844G>C p.R1615T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.104); catalogued as COSV71393265; called by muse, mutect2, varscan2
- ROBO4 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV60623058; called by muse, mutect2, varscan2
- RPP40 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.63); catalogued as COSV60291790; called by muse, mutect2, varscan2
- RPS13 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as COSV57180061; called by muse, mutect2, varscan2
- RPS28 | c.42C>T p.V14= | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as COSV56846345; called by muse, mutect2, varscan2
- RPS6KA5 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV56221371; called by muse, mutect2, varscan2
- RPS6KC1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV65298500; called by muse, mutect2, varscan2
- RRN3 | c.1776C>G p.F592L | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV52214098; called by muse, mutect2, varscan2
- RRP36 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773848628, COSV55064057, COSV55064727; called by muse, mutect2, varscan2
- RTL4 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as COSV100466107, COSV61206728; called by muse, mutect2
- RTN1 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1384963177, COSV50721492; called by muse, mutect2, varscan2
- RTN3 | c.2793G>A p.M931I (on ENST00000377819 / NM_001265589.2; = p.M135I on NM_006054.4) | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV58028101; called by muse, mutect2, varscan2
- RUNDC1 | c.1646A>G p.Q549R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.914); catalogued as COSV64511690; called by muse, mutect2, varscan2
- RUNX1T1 | c.1627G>C p.D543H (on ENST00000265814 / NM_001198628.1; = p.D516H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56137534; called by muse, mutect2, varscan2
- RYR2 | c.10091G>A p.R3364K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV63678832; called by muse, mutect2, varscan2
- RYR3 | c.8758G>A p.D2920N (on ENST00000389232; = p.D2921N on NM_001036.6) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV66784786; called by muse, mutect2, varscan2
- SACS | c.4951C>G p.Q1651E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66538459; called by muse, mutect2, varscan2
- SALL4 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as rs1052759380, COSV53851509; called by muse, mutect2, varscan2
- SAMD14 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as rs541345234; called by muse, mutect2, varscan2
- SAMD3 | c.265C>G p.R89G | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV60775280; called by muse, mutect2, varscan2
- SAMD9 | c.3132A>T p.E1044D | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV66074456; called by muse, mutect2, varscan2
- SBDS | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV55887376; called by muse, mutect2, varscan2
- SCAF1 | c.2021C>G p.S674W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); catalogued as COSV62182992; called by muse, mutect2, varscan2
- SCN9A | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV57600921; called by muse, mutect2, varscan2
- SCUBE2 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58542016; called by muse, mutect2, varscan2
- SEMA5A | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as COSV66789979; called by muse, mutect2, varscan2
- SEMA6C | c.1597C>G p.Q533E | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV59001964, COSV59003974; called by muse, mutect2, varscan2
- SERPINB5 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.454); catalogued as COSV66975301; called by muse, mutect2, varscan2
- SERPINB8 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV54639442; called by muse, mutect2, varscan2
- SERPINI2 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52985652; called by muse, mutect2, varscan2
- SETBP1 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56318934; called by muse, mutect2, varscan2
- SH3BP4 | c.2772G>A p.M924I | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV60643500; called by muse, mutect2, varscan2
- SH3BP5L | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV63539031; called by muse, mutect2, varscan2
- SH3KBP1 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as COSV65646733; called by muse, mutect2, varscan2
- SH3KBP1 | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65640539; called by muse, mutect2, varscan2
- SHMT1 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs778033192, COSV57398545; called by muse, mutect2, varscan2
- SHPRH | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.066); catalogued as rs760250539, COSV51605803, COSV51607850; called by muse, mutect2, varscan2
- SHTN1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53381622; called by muse, varscan2
- SI | c.4702C>T p.P1568S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52274037, COSV52275696; called by muse, mutect2, varscan2
- SIDT1 | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53500191; called by muse, mutect2, varscan2
- SIMC1 | c.2503G>T p.E835* (on ENST00000443967 / NM_001308196.1; = p.E420* on NM_198567.5) | Nonsense Mutation (SNP) | VAF 25/83 reads (30%) | catalogued as COSV53799916; called by muse, mutect2, varscan2
- SIN3A | c.300G>C p.Q100H | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV64582507; called by muse, mutect2, varscan2
- SIPA1L3 | c.2590G>C p.E864Q | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV55912368; called by muse, mutect2, varscan2
- SIX2 | c.227C>G p.S76W | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57390668; called by muse, mutect2, varscan2
- SKAP1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs761604918, COSV61145889; called by muse, mutect2, varscan2
- SLC12A5 | c.2176G>A p.G726S (on ENST00000454036 / NM_001134771.2; = p.G703S on NM_020708.5) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867133542, COSV54791858; called by mutect2, varscan2
- SLC14A1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354167856, COSV58931596; called by muse, mutect2, varscan2
- SLC16A3 | c.1124-1G>A p.X375_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as COSV58364301; called by muse, mutect2, varscan2
- SLC22A18 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56539728; called by muse, mutect2, varscan2
- SLC22A25 | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV60595448; called by muse, mutect2, varscan2
- SLC22A3 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.029); catalogued as COSV51712626; called by muse, mutect2, varscan2
- SLC24A2 | c.279G>C p.K93N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV53862562, COSV99647442; called by muse, mutect2, varscan2
- SLC26A5 | c.1996G>C p.E666Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs748052395, COSV100100165, COSV59700454; called by mutect2, varscan2
- SLC32A1 | c.1453C>G p.L485V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54146386; called by muse, mutect2, varscan2
- SLC33A1 | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV63946988; called by muse, mutect2, varscan2
- SLC4A3 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.019); catalogued as rs140581019, COSV56093375; called by muse, mutect2, varscan2
- SLC6A1 | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55114416; called by muse, mutect2, varscan2
- SLC7A4 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV60383199; called by muse, mutect2, varscan2
- SLIT3 | c.2197G>C p.E733Q | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV60603278, COSV60626383; called by muse, mutect2, varscan2
- SLITRK3 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53847277, COSV99580297; called by muse, mutect2, varscan2
- SLK | c.1710G>C p.Q570H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV59824917; called by muse, mutect2, varscan2
- SMARCAD1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV62773861; called by muse, mutect2, varscan2
- SMC3 | c.2775G>A p.M925I | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.03); catalogued as COSV62419732; called by muse, varscan2
- SMC4 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs771029178, COSV58446742; called by muse, mutect2, varscan2
- SMPD4 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60079706; called by muse, mutect2, varscan2
- SMTNL1 | c.577G>A p.D193N (on ENST00000399154; = p.D219N on NM_001105565.2) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs774755688, COSV67699521; called by muse, varscan2
- SNCB | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV59527783; called by muse, mutect2, varscan2
- SNX13 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.142); catalogued as COSV68064625; called by muse, mutect2, varscan2
- SNX32 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57449318; called by muse, mutect2, varscan2
- SOGA3 | c.2677G>C p.E893Q | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs931724948, COSV64106193; called by muse, mutect2, varscan2
- SORCS1 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV53857436; called by muse, mutect2, varscan2
- SP100 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.511); catalogued as COSV50977079; called by muse, mutect2, varscan2
- SPATA20 | c.2110-1G>C p.X704_splice (on ENST00000356488 / NM_001258372.1; = p.X720_splice on NM_022827.4) | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV50066321; called by muse, mutect2, varscan2
- SPIDR | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.481); catalogued as COSV52374320; called by muse, mutect2, varscan2
- SPIN3 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.28); catalogued as COSV66529118, COSV66529137; called by muse, mutect2, varscan2
- SPOCK1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.091); catalogued as COSV56445845; called by muse, mutect2, varscan2
- SPTA1 | c.7035C>G p.D2345E | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV63751687; called by muse, mutect2, varscan2
- SPTBN1 | c.2198C>T p.S733L | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1302344153, COSV61687598; called by muse, mutect2, varscan2
- SPTLC1 | c.965C>G p.S322C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs755863760, COSV52763712; called by muse, mutect2
- SPTLC2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV53639339; called by muse, mutect2, varscan2
- SRCAP | c.9240G>C p.K3080N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV52670711; called by muse, mutect2, varscan2
- SRPRA | c.411G>C p.K137N | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV55006076, COSV99702914; called by muse, mutect2, varscan2
- SRSF6 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV54827401; called by muse, varscan2
- SRSF9 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV57584439, COSV99986756; called by muse, mutect2, varscan2
- SSBP2 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); catalogued as COSV57796006; called by muse, mutect2, varscan2
- SSR1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as COSV55202783; called by muse, mutect2, varscan2
- STARD8 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV52924806; called by muse, mutect2, varscan2
- STEAP1 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as rs753918145, COSV51881413; called by muse, mutect2, varscan2
- STMN3 | c.149C>G p.S50* | Nonsense Mutation (SNP) | VAF 33/159 reads (21%) | catalogued as COSV100899864; called by muse, mutect2, varscan2
- STRN | c.998A>T p.K333M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV55747322; called by muse, mutect2, varscan2
- STRN4 | c.2107C>G p.L703V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV52185910, COSV52187085; called by muse, mutect2, varscan2
- STX16 | c.646C>T p.R216W (on ENST00000371141 / NM_001001433.3; = p.R195W on NM_003763.6) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs770123369, COSV56604992; called by muse, mutect2, varscan2
- SUCO | c.2845G>C p.E949Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55264091; called by muse, mutect2, varscan2
- SUPT16H | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs773189447, COSV52848198; called by muse, mutect2, varscan2
- SWT1 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV62255267; called by muse, mutect2
- SYNE2 | c.10163C>T p.S3388L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs759908590, COSV59947053; called by muse, mutect2, varscan2
- SYNE2 | c.10932C>G p.I3644M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV59947057; called by muse, mutect2, varscan2
- SYT14 | c.951G>C p.Q317H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV55052359, COSV55055398; called by muse, mutect2, varscan2
- SYT16 | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); catalogued as COSV70856127; called by muse, mutect2, varscan2
- TANC1 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55086376; called by muse, varscan2
- TANC1 | c.2842G>A p.E948K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.34); catalogued as rs752902036, COSV55086386, COSV55093631; called by muse, varscan2
- TANGO6 | c.2601G>C p.Q867H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.831); catalogued as COSV55763720; called by muse, mutect2, varscan2
- TAS2R43 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV67854910, COSV67858412; called by muse, mutect2, varscan2
- TASOR2 | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60166958, COSV60169409; called by muse, mutect2, varscan2
- TBC1D31 | c.2459G>C p.R820T | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV54865340; called by muse, varscan2
- TBC1D9 | c.2979G>C p.K993N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as rs781302004, COSV71307264; called by muse, mutect2
620 further variants in this file (244 protein-altering or splice-affecting, 340 silent, 36 other) are not listed here.
